CCDI case PBCNMB — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/f4585e0f-ae5d-4d11-86c6-76df71313b67

Demographics
Sex at birth: female; Race: asian.

Diagnoses (1)
1. Astrocytoma, NOS: ICD-O-3 morphology code: 9400/3; Tissue or organ of origin: Parietal lobe; Age at diagnosis: 13.4 years (4,877 days).

Biospecimens (2 samples)
- Sample 0DW41P: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DW42I: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
